HCMI case HCM-CSHL-0368-D37 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Ductal and Lobular Neoplasms; Primary site: Gallbladder. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/1d8a21f2-0671-45ce-ba44-94d3d0d29dd4

Demographics
Sex at birth: male; Race: white; Ethnicity: hispanic or latino; Year of birth: 1952; Vital status: Alive.

Diagnoses (1)
1. Noninfiltrating intraductal papillary adenocarcinoma: ICD-O-3 morphology code: 8503/2; ICD-10 code: D37.6; Tissue or organ of origin: Gallbladder; Site of resection or biopsy: Gallbladder; Classification of tumor: Premalignant; Age at diagnosis: 65.9 years (24,078 days); AJCC clinical stage: Stage 0; AJCC pathologic stage: Stage 0; Tumor grade: GB; Prior malignancy: yes; Prior treatment: No.
   Pathology details: Lymph nodes positive: 0; Lymph nodes tested: 16; Lymphatic invasion present: No; Necrosis present: No; Vascular invasion present: No.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 11 days.
   Recorded as not given: neoadjuvant treatment (type not reported); adjuvant Pharmaceutical Therapy, NOS, for residual disease; adjuvant Radiation Therapy, NOS, for residual disease.

Follow-up (2 entries)
- Days to follow up: 654 days (1.8 years); Disease response: Complete Response; Progression or recurrence: No.
- Follow-up contact recording only the day: day 391.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 92 kg; Height: 177.8 cm; BMI: 29.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol drinks per day: 0; Alcohol days per week: 0.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample HCM-CSHL-0368-D37-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Buffy Coat; Preservation method: Frozen.
- Sample HCM-CSHL-0368-D37-31A: Sample type: Neoplasms of Uncertain and Unknown Behavior; Tissue type: Tumor; Tumor descriptor: Premalignant; Specimen type: Solid Tissue; Preservation method: Frozen.
  Slide HCM-CSHL-0368-D37-31A-01-S1-HE: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 10; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 3.
  Slide HCM-CSHL-0368-D37-31A-01-S2-HE: Section location: Bottom; Percent tumor cells: 90; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 10; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 3.
- Sample HCM-CSHL-0368-D37-85P: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Premalignant; Specimen type: 3D Organoid; Preservation method: Frozen.
